Surgical pathology report (de-identified scan), TCGA case TCGA-05-4420, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4420-01A (Primary Tumor).

Main diagnosis/diagnoses:

Central to peripheral bronchopulmonary, histologically mixed adenocarcinoma of the right lower lobe of the lung with a predominant papillary and small acinar component, slight mucin formation and main localization in segments 7 to 9.

TNM classification on the basis of this material pT2 pN0 pMX R0, stage IB.

C34.3 M8255/3.

Comment/supplementary remark:

The tumor has extended to S4 of the middle lobe, the resection margin of the bronchus and the vessels as well as all the lymph nodes removed and identified are tumor-free.

Source: NCI Genomic Data Commons file c538c49d-866b-4ce7-9b6d-4218d2dd8307 (TCGA-05-4420.682A1FDC-41DD-441B-831C-FE3CF834638E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).